TCGA case TCGA-LN-A4A2 — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: ILSBIO. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a91c3f09-5f48-4b54-b669-c768f9fe9682

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 57 years; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.4; Tissue or organ of origin: Middle third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 57.8 years (21,122 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 380 days (1.0 years); Sites of involvement: Esophagus, Middle Third.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin; Days to treatment start: 47 days; Days to treatment end: 83 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 47 days; Days to treatment end: 83 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; Radiation Therapy, NOS, preoperative.

Follow-up (3 entries)
- Days to follow up: 4 days; Disease response: Tumor Free.
- Days to follow up: 380 days (1.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 60.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 165 cm; BMI: 21.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Alcohol history: Yes; Alcohol drinks per day: 2; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LN-A4A2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 300 mg.
  Slide TCGA-LN-A4A2-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 45; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-LN-A4A2-01A-03-TSC: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-LN-A4A2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LN-A4A2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Alcohol consumption frequency: 7; History reflux disease indicator: No; Number of relatives diagnosed: 0; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Lymph nodes examined: No; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 380 days; disease-specific survival: no event (censored), 380 days; disease-free interval: no event (censored), 380 days; progression-free interval: no event (censored), 380 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LN-A4A2-01A-31D-A25X-01): tumor purity 0.56, ploidy 3.21, whole-genome doublings 1.
